TCGA case TCGA-41-3393 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6fac5bce-2bc0-4234-9e3e-11891c2fe00e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Dead; Days to death: 135 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 81.9 years (29,904 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 51 days; Days to treatment end: 95 days; Treatment dose: 6,000 cGy; Chemo concurrent to radiation: Yes; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 51 days; Days to treatment end: 95 days; Number of cycles: 1; Treatment dose: 5,040 mg; Prescribed dose: 120; Prescribed dose units: mg; Route of administration: Oral.

Follow-up (2 entries)
- Days to follow up: 135 days; Disease response: With Tumor.
- ECOG performance status: 4; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-41-3393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-41-3393-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 60; Percent stromal cells: 0.
  Slide TCGA-41-3393-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 2.
- Sample TCGA-41-3393-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-41-3393-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Steroetactic Brain Biopsy; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment: Pharmaceutical therapy drug name: Temodar; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent chemoradiation.
- Drug treatment, Route of administrations: Route of administration: PO.
- Radiation treatment: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent Chemoradiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 135 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 135 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 135 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-41-3393-01): tumor purity 0.67, ploidy 2.03, whole-genome doublings 0 (call status: legacy_call).
